Somatic mutation profile of tumor specimen C3N-02271-01 (aliquot CPT0181670011) from CPTAC case C3N-02271, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.9 years (21,506 days).
Specimen C3N-02271-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93776364-9f07-4a90-abc6-640106cc1746.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02271-31 (Blood Derived Normal), aliquot CPT0181730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6d4d6fd-2b7a-49e2-a05e-cbfbc536412e

The open-access MAF lists 35 somatic variants for this specimen: 31 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 3, Splice Region 2, Splice Site 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 97/414 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6981G>A p.M2327I | Missense Mutation (SNP) | VAF 27/206 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878855328, COSV63868602, COSV63869693, COSV63874461; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALG10B | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372347662; called by muse, mutect2, varscan2
- CGN | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs191516238; called by muse, mutect2, varscan2
- GRTP1 | c.921G>A p.Q307= | Splice Region (SNP) | VAF 40/314 reads (13%) | catalogued as rs768221334; called by muse, mutect2, varscan2
- INO80 | c.2561A>G p.N854S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs138784219; called by muse, mutect2, varscan2
- KIRREL3 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs372003906; called by muse, mutect2, varscan2
- MATN3 | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs375672946; called by muse, mutect2, varscan2
- MSTO1 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs554914910; called by muse, mutect2, varscan2
- PACS2 | c.1050G>A p.P350= | Splice Region (SNP) | VAF 42/259 reads (16%) | catalogued as rs782325438; called by muse, mutect2, varscan2
- PRPF8 | c.5517G>T p.W1839C | Missense Mutation (SNP) | VAF 78/552 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59268573; called by muse, mutect2, varscan2
- PTEN | c.100G>C p.A34P | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100909680, COSV64293534, COSV64307061; called by muse, mutect2, varscan2
- PTEN | c.165-2A>C p.X55_splice | Splice Site (SNP) | VAF 33/174 reads (19%) | catalogued as CS982330, COSV64298665, COSV64299631, COSV64301833; called by muse, mutect2, varscan2
- REV3L | c.4535G>A p.R1512Q | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs776967346, COSV100725683; called by muse, mutect2
- SCUBE3 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771662273; called by muse, mutect2
- TAOK3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 66/476 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs776166030; called by muse, mutect2, varscan2
- AKT3 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AQR | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGEF25 | c.1083C>A p.F361L | Missense Mutation (SNP) | VAF 82/514 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- BRWD3 | c.4726C>T p.L1576F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FER | c.1692A>G p.I564M | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- HNRNPUL1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- NOL4L | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR11H2 | c.258G>T p.L86F (on ENST00000556246; = p.L97F on NM_001197287.1) | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RALGAPB | c.4387A>G p.I1463V | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SF3B3 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SHCBP1 | c.1936A>T p.M646L | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAB3 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 58/372 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TBL3 | c.249dup p.A84Sfs*47 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- TEX30 | c.71C>G p.P24R | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BCOR | c.4902C>T p.S1634= (on ENST00000378444 / NM_001123385.2; = p.S1600= on NM_017745.6) | Silent (SNP) | VAF 46/345 reads (13%) | catalogued as rs747409134, COSV60716874; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRGPRG | c.606C>T p.G202= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- TRPM5 | c.1713G>A p.T571= | Silent (SNP) | VAF 47/269 reads (17%) | catalogued as rs746094271; called by muse, mutect2, varscan2
- ALDH3B1 | c.162+190G>T | Intron (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
